Somatic mutation profile of tumor specimen 0DMOXJ from CCDI case PBCAWA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.4 years (4,911 days).
Specimen 0DMOXJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c08d149a-1862-4055-b471-2b011fcc7a95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMOXO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/677fc580-7fad-47cd-857a-ebe99be03e8f

The open-access MAF lists 67 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 9, 5'UTR 5, Nonsense Mutation 4, 3'UTR 2, RNA 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 50/672 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2
- NF1 | c.5902C>T p.R1968* (on ENST00000358273 / NM_001042492.3; = p.R1947* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 92/642 reads (14%) | catalogued as rs137854552, CM900173, COSV62199973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCHS2 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs553108932; called by muse, mutect2, varscan2
- EXTL1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs781574807; called by muse, mutect2, varscan2
- HEATR5B | c.3559C>A p.H1187N | Missense Mutation (SNP) | VAF 128/553 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV51856438; called by muse, mutect2, varscan2
- HORMAD1 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 137/708 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1264615418; called by mutect2, varscan2
- KMT2B | c.3247C>T p.R1083* | Nonsense Mutation (SNP) | VAF 36/225 reads (16%) | catalogued as COSV55858123; called by muse, mutect2, varscan2
- MYPN | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 93/438 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV62732503; called by muse, mutect2, varscan2
- P3H2 | c.1042T>A p.Y348N | Missense Mutation (SNP) | VAF 189/921 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV60019450; called by muse, mutect2, varscan2
- RHCE | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 91/732 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs1332272763; called by muse, mutect2, varscan2
- SMYD2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 141/547 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs769275348; called by muse, mutect2, varscan2
- TTN | c.99202C>T p.R33068C (on ENST00000591111; = p.R25644C on NM_003319.4) | Missense Mutation (SNP) | VAF 126/866 reads (15%) | PolyPhen probably damaging (0.942); catalogued as rs530959653, COSV60007982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2W | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 99/619 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1298728912; called by muse, mutect2, varscan2
- ZGRF1 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 135/714 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs189716668, COSV58411024; called by muse, mutect2, varscan2
- ADSL | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 157/570 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BABAM1 | c.907del p.L303Cfs*66 | Frame Shift Del (DEL) | VAF 48/224 reads (21%) | called by mutect2, pindel, varscan2
- C18orf63 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 43/515 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CALD1 | c.2273A>G p.K758R (on ENST00000361675 / NM_033138.4; = p.K503R on NM_004342.7) | Missense Mutation (SNP) | VAF 75/506 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDCP2 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.4934G>A p.W1645* | Nonsense Mutation (SNP) | VAF 84/818 reads (10%) | called by muse, mutect2, varscan2
- FAT1 | c.9040C>A p.L3014M | Missense Mutation (SNP) | VAF 108/626 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17RA | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- ITPKB | c.2677G>T p.V893L | Missense Mutation (SNP) | VAF 33/472 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2
- MUC17 | c.1001C>A p.T334N | Missense Mutation (SNP) | VAF 100/494 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH4 | c.3141A>T p.K1047N | Missense Mutation (SNP) | VAF 152/658 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NDST4 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 218/1041 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- OR4C46 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 124/671 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- P2RY10 | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 113/281 reads (40%) | called by muse, mutect2, varscan2
- POGLUT2 | c.1445C>G p.P482R | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PSKH2 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 106/673 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PTEN | c.42_44del p.R15del | In Frame Del (DEL) | VAF 108/493 reads (22%) | called by mutect2, pindel, varscan2
- SP3 | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 60/1166 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2
- TRIP12 | c.967A>G p.S323G | Missense Mutation (SNP) | VAF 93/677 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- UBR3 | c.1297A>C p.S433R | Missense Mutation (SNP) | VAF 90/1278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- VWA7 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WFDC12 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 53/594 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2
- XRCC5 | c.1804G>T p.V602L | Missense Mutation (SNP) | VAF 108/1046 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C2CD4D | c.777T>C p.C259= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as rs1233739274; called by muse, mutect2, varscan2
- CACNA1S | c.5094T>C p.A1698= | Silent (SNP) | VAF 58/286 reads (20%) | called by muse, mutect2, varscan2
- COLGALT1 | c.1449C>T p.R483= | Silent (SNP) | VAF 62/272 reads (23%) | catalogued as rs370763953; called by muse, mutect2, varscan2
- FANCG | c.1323A>G p.G441= | Silent (SNP) | VAF 74/409 reads (18%) | called by muse, mutect2, varscan2
- FNBP1L | c.1551A>G p.P517= (on ENST00000271234 / NM_001164473.2; = p.P459= on NM_017737.5) | Silent (SNP) | VAF 152/713 reads (21%) | catalogued as rs760113054; called by muse, mutect2, varscan2
- KIAA1210 | c.1602A>G p.G534= | Silent (SNP) | VAF 20/368 reads (5%) | called by muse, mutect2
- KRTAP2-4 | c.339C>T p.C113= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs751495363, COSV67458593; called by mutect2, varscan2
- MECOM | c.3027T>C p.Y1009= (on ENST00000468789 / NM_001105078.4; = p.Y1197= on NM_004991.4) | Silent (SNP) | VAF 54/666 reads (8%) | catalogued as rs144184901; called by muse, mutect2
- MUC7 | c.171G>A p.P57= | Silent (SNP) | VAF 110/617 reads (18%) | catalogued as rs758265177, COSV59217070; called by muse, mutect2, varscan2
- OR1I1 | c.321C>T p.F107= | Silent (SNP) | VAF 52/266 reads (20%) | catalogued as rs374219835; called by muse, mutect2, varscan2
- SLC7A13 | c.339G>T p.L113= | Silent (SNP) | VAF 58/581 reads (10%) | catalogued as rs201244158, COSV52533412; called by mutect2, varscan2
- TSPAN8 | c.45C>T p.F15= | Silent (SNP) | VAF 55/940 reads (6%) | called by muse, mutect2
- UNC5C | c.186A>T p.P62= | Silent (SNP) | VAF 142/774 reads (18%) | called by muse, mutect2, varscan2
- FEV | c.-64G>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- FOXE1 | c.-12G>A | 5'UTR (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2
- GGA2 | c.-27C>G | 5'UTR (SNP) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- HELT | c.133-38C>T | Intron (SNP) | VAF 28/119 reads (24%) | catalogued as rs781744007; called by muse, mutect2, varscan2
- HNRNPK | c.1192-54G>C | Intron (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- IL15 | c.110+596C>A | Intron (SNP) | VAF 59/473 reads (12%) | catalogued as rs914845311; called by muse, mutect2, varscan2
- IL15 | c.110+597C>A | Intron (SNP) | VAF 60/474 reads (13%) | called by muse, mutect2, varscan2
- KLK3 | c.631-385T>C | Intron (SNP) | VAF 31/306 reads (10%) | catalogued as COSV58099047; called by muse, mutect2, varscan2
- NIFK | c.353-76T>A | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- NRGN | c.-58G>T | 5'UTR (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- OSCAR | c.*420G>A | 3'UTR (SNP) | VAF 57/305 reads (19%) | catalogued as rs771722966, COSV52927021; called by muse, mutect2, varscan2
- P3H1 | c.2056-42G>C | Intron (SNP) | VAF 25/375 reads (7%) | called by muse, mutect2
- RBMS1 | c.251+72T>A | Intron (SNP) | VAF 35/434 reads (8%) | called by muse, mutect2
- SERPINA1 | c.*67G>T | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- TMEM183B | n.967G>C | RNA (SNP) | VAF 68/718 reads (9%) | catalogued as rs1559990966; called by muse, mutect2, varscan2
- USHBP1 | c.1047-26A>G | Intron (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
- ZNF729 | c.-8C>A | 5'UTR (SNP) | VAF 78/378 reads (21%) | called by muse, mutect2, varscan2
